Gene-level copy-number profile of tumor specimen ALCH-AE7M-TTP1-A from ALCHEMIST case ALCH-AE7M, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 67.4 years (24,602 days).
Specimen ALCH-AE7M-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a3dc9491-591e-4b6e-9b64-547c1b07b28a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AE7M-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,714 have no estimate.
https://portal.gdc.cancer.gov/files/3cbaea01-3a1c-4e20-8d95-158ad4c901cf

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 186; copy number 1: 25,157; copy number 2: 30,195; copy number 3: 2,493; copy number 4: 666; copy number 5: 36; copy number 6: 14; copy number 7: 52; copy number 8: 4; copy number 9: 25; copy number 10: 44; copy number 13: 22; copy number 14: 15.

Homozygous deletions (total copy number 0; autosomes only): 24 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:36,769,812–36,775,768, 1 gene: AC117945.1.
- chr6:29,887,294–29,934,286, 8 genes: AL645929.1, HLA-H, HLA-T, DDX39BP1, MCCD1P1, HCG4B, HLA-K, HLA-U.
- chr14:106,421,711–106,422,218, 1 gene (within-gene range 0–3): IGHV4-39.
- chr14:106,436,415–106,461,055, 4 genes (within-gene range 0–3): AC244452.1, IGHVII-40-1, IGHV3-41, HOMER2P1.
- chr14:106,470,264–106,470,800, 1 gene (within-gene range 0–3): IGHV3-43.
- chr15:20,344,736–20,359,166, 1 gene: AC026495.1.
- chr15:90,839,641–90,883,458, 3 genes: AC124248.1, RN7SL363P, FURIN.
- chr15:90,920,218–90,963,125, 5 genes (within-gene range 0–1): AC068831.3, HDDC3, UNC45A, RCCD1-AS1, RCCD1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 191 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:180,692,104–181,409,321, 8 genes, copy number 5 (within-gene range 3–5): SCHLAP1, AC104820.1, FTH1P20, RPL27AP3, UBE2E3, AC104076.1, AC068196.1, LINC01934.
- chr3:176,415,439–183,910,936, 134 genes, copy number 7–13 (broad region; genes not listed).
- chr3:191,329,085–191,398,659, 1 gene, copy number 7 (within-gene range 4–7): CCDC50.
- chr3:191,461,163–191,461,456, 1 gene, copy number 7: PYDC2.
- chr6:53,794,497–54,266,280, 8 genes, copy number 5: LRRC1, AL033384.2, MLIP, AL033384.1, MLIP-AS1, MLIP-IT1, ERHP2, AL359380.1.
- chr6:63,193,072–63,616,361, 15 genes, copy number 14: AL450346.1, FKBP1C, SPTLC1P3, AL450346.2, LGSN, AL121949.3, AL121949.2, AL121949.1, EEF1B2P5, PTP4A1, RPL7AP34, AL135905.1, AL135905.2, AL513043.1, RPL9P18.
- chr7:102,681,836–102,690,469, 1 gene, copy number 8: RASA4DP.
- chr11:69,294,151–69,704,022, 11 genes, copy number 5: MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, CCND1, LTO1, FGF19.
- chr16:629,239–667,833, 6 genes, copy number 6 (within-gene range 2–6): WFIKKN1, METTL26, MCRIP2, AL022341.1, WDR90, AL022341.2.
- chr16:678,504–692,554, 6 genes, copy number 6 (within-gene range 2–6): LINC02867, Z92544.2, STUB1, JMJD8, WDR24, Z92544.1.

Autosomal genes at a single copy (total copy number 1): 23,023. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
